Gene-level copy-number profile of tumor specimen TCGA-HC-7745-01A from TCGA case TCGA-HC-7745, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.9 years (24,078 days).
Specimen TCGA-HC-7745-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.4e61e622-4c90-4f9c-a7c1-f1b37f1c32a8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-7745-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (sample pair TCGA-HC-7745-01A|TCGA-HC-7745-10A); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/89bcae17-47d6-4e5a-b65c-0838a3839266

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 9,184; copy number 2: 47,104; copy number 3: 2,340; copy number 4: 1,182.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-7745-01A-11D-2112-01): tumor purity 0.38, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:6,462,144–6,590,653, 3 genes (within-gene range 0–4): RPL6P27, AP005202.2, LINC01387.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,803. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
